Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IH, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IH-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT PELVIC LYMPH NODES:
Six lymph nodes, no tumor present (0/6).
- (B) RIGHT PELVIC LYMPH NODES:
Four lymph nodes, no tumor present (0/4).
- (C) POSTERIOR BLADDER NECK:
To be reported in an addendum.
- (D) PROSTATE AND SEMINAL VESICLES:
To be reported in an addendum.

OSCE *ICD0-3*
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
JW 11/24/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) LEFT PELVIC LYMPH NODES - Received is a 4.7 x 3.2 x 1.2 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal seven possible lymph nodes ranging from 0.2 x 0.2 x 0.1 cm - 5.5 x 2.0 x 0.8 cm.
SECTION CODE: A1, two possible lymph nodes; A2, two possible lymph nodes; A3, one possible lymph node, serially sectioned; A4, one possible lymph node, serially sectioned; A5-A8, one possible lymph node, serially sectioned. Entire specimen is submitted.
- (B) RIGHT PELVIC LYMPH NODES - A 4.5 x 3.5 x 1.0 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal four possible lymph nodes ranging from 0.3 x 0.2 x 0.1 cm - 4.7 x 1.8 x 0.7 cm.
SECTION CODE: B1, one possible lymph node; B2, one possible lymph node, serially sectioned; B3, one possible lymph node, serially sectioned; B4-B6, one possible lymph node, serially sectioned. Entire specimen is submitted.
- (C) POSTERIOR BLADDER NECK - To be reported in an addendum.
- (D) PROXIMAL AND SEMINAL VESICLES - To be reported in an addendum.

CLINICAL HISTORY

Prostate cancer

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) POSTERIOR BLADDER NECK:

Adipose tissue with vessels and ganglion, no tumor present.
No prostatic tissue present.

(D) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3) WITH TERTIARY GLEASON GRADE 5 COMPONENT. (SEE COMMENT).

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE.

MARGINS OF RESECTION FREE OF TUMOR.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma, one in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the right lateral, right posterolateral, right posterior, mid posterior and left posterior peripheral zone. This tumor focus measures 2.0 x 2.0 cm in the largest cross-sectional dimension, and it is present in two cross sections and extensively in the apex and base regions. This tumor focus exhibits extraprostatic extension in the right superior neurovascular bundle region and right bladder neck region. Extraprostatic extension is present in three sections and the added length of extraprostatic extension is 9.5 mm. The margins of resection are free of tumor. The second tumor focus is located in the right and left transition zone. This tumor focus measures 3.0 x 1.0 cm in the largest cross-sectional dimension, and it is present in two cross sections and extensively in the apical region. This tumor focus is confined to the prostate. All margins of resection are free of tumor.

GROSS DESCRIPTION

(C) POSTERIOR BLADDER NECK – A portion of tan-gray tissue (1.1 x 0.8 x 0.4 cm). Submitted in toto in C.

(D) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.2 x 2.6 x 3.2 cm, 35 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated on the right side of the prostate. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right posterolateral peripheral zone of the two cross sections of the prostate.

[page 3 of 3]
Specimen Date/Time:

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: D1-D4, right seminal vesicle and segment of right vas deferens from the base towards the tip; D5-D7, left seminal vesicle and segment of left vas deferens from the base towards the tip; D8, D9, prostatic base, right border; D10, D11, prostatic base, right posterior border; D12-D15, prostatic base, central portion; D16, D17, prostatic base, left border; D18-D20, prostatic base, left posterior border; D21-D23, apex anterior; D24, apex left; D25, D26, apex posterior; D27, D28, apex right; D29, detached portions of margin of resection according to the specimen radiograph; D30-D37, sections of the two cross sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

Orange ink (D30) indicates surfaces that do not represent the true margin of resection. Multiple blocks (D30, 31, 36 and 37) submitted for decalcification.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file cf486146-e0f4-4364-b1d5-1848ba66d0eb (TCGA-KK-A8IH.E2FC2177-CB74-4E23-B24D-68F4ECEA57C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).